Gene-level copy-number profile of tumor specimen TCGA-OR-A5KZ-01A from TCGA case TCGA-OR-A5KZ, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 42.7 years (15,594 days).
Specimen TCGA-OR-A5KZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.b297985e-db11-4529-a32b-28b9b34c4173.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5KZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dbaf3ac6-6af9-4cb0-adcc-e7768b797b39

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 4,308; copy number 2: 34,203; copy number 3: 17,632; copy number 4: 3,581; copy number 5: 81.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5KZ-01A-11D-A29H-01): tumor purity 0.95, ploidy 2.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:39,175,646–39,229,588, 1 gene: CDKL4.
- chr2:39,283,657–39,283,791, 1 gene: AC007684.1.
- chr4:180,573,464–180,574,027, 1 gene: NDUFB5P1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr22:28,800,683–29,057,488, 4 genes (within-gene range 0–2): Z93930.2, Z93930.1, ZNRF3, ZNRF3-IT1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 81 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:82,033,533–82,961,926, 1 gene, copy number 5 (within-gene range 4–5): AC060765.2.
- chr8:82,514,568–84,921,844, 15 genes, copy number 5: AC060765.1, AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419, AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2.
- chr20:21,947,647–24,318,086, 65 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,887. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
